Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5KU, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5KU-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Tumor Adrenal Cortical of unknown/
uncertain behavior 8370/1
Site: Adrenal Gland Cortex C74.0
Pathology from L Nephrectomy and lymph
nodes. No Adrenal pathology

CW 2/6/13

Procedure: L nephrectomy, preirenal and paraaortal LN

Gross description: 11 x 10.5 x 9cm, 497g

Diagnosis: adrenocortical carcinoma, small LN in the specimen are free of tumor

Reference Pathology:

Diagnosis: adrenocortical carcinoma, KI67 5-10%, high grade 5 per 10 hpf

Weiss score: 2

Hough score: 1.69

Van Slooten score: 5.7

Proven - if proven get more path
info - may not ship if not malignant

Criteria CW 1/16/13

	Yes	No
Pathology Discrepancy		
Metastasis Discrepancy		

[page 2 of 2]
Patient # from Tissue Source Site

Date of report

Date of Surgery/specimen collection

Site (confirmed to be adrenal) with laterality indicated
Left

Tumor size(s)
11x10.5x9cm

Histologic diagnosis
ACC

Lymph Node Status
0/4

Pathologic information
T2N0

Weiss score
2, but KI67 5-10% and Dx of ACC, by reference pathologist

Source: NCI Genomic Data Commons file 409c9cc0-29b5-451a-ac91-ebbd98f36d4a (TCGA-OR-A5KU.F9F537ED-3066-4E99-B6D1-112D6C4551F0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).